Somatic mutation profile of tumor specimen TCGA-AA-3980-01A (aliquot TCGA-AA-3980-01A-02W-0995-10) from TCGA case TCGA-AA-3980, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AA-3980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2af3d644-8804-4f20-ae69-2d06fa186fd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3980-10A (Blood Derived Normal), aliquot TCGA-AA-3980-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d19cb5f7-8b28-47eb-9103-28d28fc6d597

The open-access MAF lists 105 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 20, Nonsense Mutation 6, Splice Region 2, Intron 2, Frame Shift Del 1, Splice Site 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 55/111 reads (50%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BTD | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514429, CM0910681, COSV57729900; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CARD11 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 96/219 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.432); catalogued as rs577877958, COSV101211076, COSV67802724; called by muse, mutect2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 39/67 reads (58%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99532382; called by muse, mutect2
- ADD2 | c.705G>A p.A235= | Splice Region (SNP) | VAF 64/161 reads (40%) | catalogued as rs781804198, COSV52472118; called by muse, mutect2, varscan2
- ARHGAP36 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99035104; called by muse, mutect2, varscan2
- ATP11C | c.399T>A p.N133K | Missense Mutation (SNP) | VAF 361/889 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV59566460, COSV59574975; called by muse, mutect2, varscan2
- ATR | c.5851C>T p.R1951* | Nonsense Mutation (SNP) | VAF 122/275 reads (44%) | catalogued as rs758234545, COSV63389101; called by muse, varscan2
- BCOR | c.2330C>G p.P777R | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.265); catalogued as COSV100652726; called by muse, mutect2, varscan2
- C12orf29 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765324047, COSV58356642; called by mutect2, varscan2
- C1orf52 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 108/225 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV53999912; called by muse, varscan2
- CACNA1C | c.4039C>T p.R1347W | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100214272, COSV100215267; called by muse, mutect2, varscan2
- CACNA1S | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as rs370661912; called by muse, mutect2, varscan2
- CCDC85A | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339333; called by muse, mutect2, varscan2
- CDC42EP4 | c.373A>T p.K125* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100231688; called by muse, mutect2, varscan2
- CFAP54 | c.8184G>C p.K2728N | Missense Mutation (SNP) | VAF 88/432 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV100732851; called by muse, mutect2, varscan2
- CHRNB2 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872511; called by muse, mutect2, varscan2
- CIZ1 | c.2065G>A p.V689I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs139103399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN6 | c.2291G>C p.R764T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100609741, COSV63166015, COSV63172489; called by muse, mutect2, varscan2
- COL14A1 | c.5000C>T p.A1667V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99917593; called by muse, mutect2, varscan2
- DCC | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497470; called by muse, mutect2, varscan2
- FAM219A | c.320C>T p.P107L (on ENST00000445726; = p.P90L on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV52621993, COSV99896596; called by muse, mutect2, varscan2
- FAM47A | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 126/386 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.432); catalogued as rs1283188238, COSV60493764; called by muse, mutect2, varscan2
- FAT1 | c.12361G>T p.G4121* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV101498604; called by muse, mutect2, varscan2
- FAT4 | c.8877T>A p.D2959E | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100626930; called by muse, mutect2, varscan2
- FHL5 | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV100459030; called by muse, mutect2, varscan2
- FMNL3 | c.2542G>A p.V848M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs199600439; called by muse, mutect2, varscan2
- FRAS1 | c.10081C>T p.H3361Y | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1352183871, COSV53650881; called by muse, varscan2
- GBE1 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs758188572, COSV70100954, COSV70102499; called by muse, mutect2, varscan2
- GLRX3 | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100487828; called by muse, varscan2
- GLYR1 | c.156-2A>G p.X52_splice | Splice Site (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100423956; called by muse, mutect2, varscan2
- HEG1 | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 90/365 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100229883; called by muse, mutect2, varscan2
- HNRNPDL | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV99786974; called by muse, mutect2
- HS6ST3 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV100939897; called by muse, varscan2
- HSPA12B | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.241); catalogued as rs1310609752, COSV54769353, COSV99654133; called by muse, mutect2, varscan2
- HTRA1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.938); catalogued as rs1565422018, COSV64563261; called by muse, mutect2, varscan2
- HTRA4 | c.773C>A p.A258D | Missense Mutation (SNP) | VAF 20/678 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.296); catalogued as COSV100205538; called by muse, mutect2
- IGHD | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as rs370301638, COSV66654856; called by muse, mutect2, varscan2
- ITGAD | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101210261; called by muse, mutect2, varscan2
- ITIH2 | c.1036T>G p.F346V | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623108; called by muse, mutect2, varscan2
- KHDRBS3 | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100878343; called by muse, mutect2
- MAGEA10 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as rs145553450, COSV54884254; called by muse, mutect2, varscan2
- MAP2 | c.3085G>T p.E1029* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99557318; called by muse, mutect2, varscan2
- MIA2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs185291670, COSV54494523; called by muse, varscan2
- MTOR | c.3908G>T p.C1303F | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100815614; called by muse, mutect2, varscan2
- MUC17 | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs761045482, COSV60304346; called by muse, mutect2, varscan2
- NUMA1 | c.5213C>G p.T1738S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV100671914; called by muse, mutect2, varscan2
- OR12D3 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs995609414, COSV101011055; called by muse, mutect2, varscan2
- P2RY4 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1342512893, COSV100996946; called by muse, mutect2, varscan2
- PCDHGB7 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1013306543, COSV99528560; called by muse, mutect2, varscan2
- PKNOX1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99372581; called by muse, mutect2, varscan2
- PLD1 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs1484817822, COSV60574497; called by muse, mutect2, varscan2
- PLEKHA4 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV99611922; called by muse, mutect2, varscan2
- PNPO | c.616C>T p.R206C (on ENST00000225573; = p.R249C on NM_018129.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs777671908, COSV56667376; called by muse, mutect2, varscan2
- PPL | c.4180C>T p.R1394C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs372808912; called by muse, varscan2
- RAPGEF4 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99909308, COSV99911997; called by muse, mutect2, varscan2
- RBPJL | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59215880; called by muse, mutect2, varscan2
- RERE | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100555090; called by muse, mutect2, varscan2
- RLF | c.2969C>T p.T990M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); catalogued as rs780719118; called by mutect2, varscan2
- SCP2 | c.374G>C p.S125T | Missense Mutation (SNP) | VAF 136/666 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV65261464, COSV65262687; called by muse, mutect2, varscan2
- SF3A1 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs370505540; called by muse, mutect2, varscan2
- SIGLEC8 | c.1470C>A p.H490Q | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV58476029; called by muse, mutect2, varscan2
- SLC9A4 | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV54839678; called by muse, mutect2, varscan2
- SNX22 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as COSV100254356; called by muse, mutect2, varscan2
- SOHLH2 | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 140/366 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV101157760; called by muse, mutect2, varscan2
- SPATA5 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99914478; called by muse, mutect2
- SPTBN4 | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs769726008, COSV58949170; called by muse, mutect2, varscan2
- STARD13 | c.3108T>G p.H1036Q (on ENST00000336934 / NM_001243476.3; = p.H918Q on NM_052851.3) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99715347; called by muse, mutect2, varscan2
- SYPL1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99163425; called by muse, mutect2
- SYTL4 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1354556665, COSV52172132; called by muse, mutect2, varscan2
- TAF4B | c.676A>C p.S226R | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV99299432; called by muse, mutect2, varscan2
- TAS2R8 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.05); catalogued as COSV99553502; called by muse, mutect2, varscan2
- TTC17 | c.162G>T p.V54= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as COSV50021478; called by muse, mutect2, varscan2
- TYR | c.1319T>G p.I440S | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99632682; called by muse, mutect2, varscan2
- VPS13B | c.10997G>T p.S3666I | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100660537; called by muse, mutect2, varscan2
- VPS13B | c.10998C>A p.S3666R | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100660540; called by muse, mutect2, varscan2
- ZMAT1 | c.1535G>A p.S512N | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV100858626; called by muse, mutect2, varscan2
- ZMYM3 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766597461, COSV100077348; called by muse, mutect2, varscan2
- ZNF571 | c.848A>C p.D283A | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100143445; called by muse, mutect2
- COG1 | c.2298_2303dup p.V767_T768dup | In Frame Ins (INS) | VAF 48/170 reads (28%) | called by pindel, varscan2
- FBXW7 | c.1453del p.V485Ffs*13 (on ENST00000281708 / NM_001349798.2; = p.V405Ffs*13 on NM_018315.5) | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- AC136428.1 | c.12G>T p.G4= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs748045198, COSV101434936; called by muse, mutect2, varscan2
- ARRDC5 | c.594C>T p.T198= (on ENST00000381781; = p.T184= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/550 reads (12%) | catalogued as COSV67788337; called by muse, mutect2, varscan2
- BACE2 | c.1497C>T p.R499= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV100160427; called by muse, mutect2
- CDH26 | c.1119G>A p.P373= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs763693105, COSV54847526, COSV54855695; called by muse, mutect2, varscan2
- DNM1 | c.1275C>A p.L425= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV57856459; called by muse, mutect2, varscan2
- DUS2 | c.162A>G p.R54= | Silent (SNP) | VAF 54/166 reads (33%) | catalogued as rs751776821, COSV62709943; called by muse, mutect2, varscan2
- FBXL19 | c.732C>T p.D244= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs376169841; called by muse, mutect2, varscan2
- GATAD2B | c.1521G>A p.T507= | Silent (SNP) | VAF 114/201 reads (57%) | catalogued as rs753763024, COSV64086249; called by muse, mutect2, varscan2
- KLK7 | c.99C>T p.G33= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs377619320; called by muse, mutect2, varscan2
- LCT | c.1188C>T p.N396= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs753445014, COSV51550063, COSV51557964; called by muse, mutect2, varscan2
- NMRAL1 | c.624C>T p.V208= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs200907550, COSV99361599; called by muse, varscan2
- OR8K1 | c.438A>C p.V146= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV54404743; called by muse, mutect2, varscan2
- PRUNE2 | c.7782C>T p.F2594= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100944172; called by muse, mutect2, varscan2
- RANBP2 | c.5694T>C p.F1898= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV51709245; called by muse, mutect2, varscan2
- SLC18A2 | c.387G>T p.V129= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV100041253; called by muse, mutect2, varscan2
- SLIT3 | c.591G>T p.L197= | Silent (SNP) | VAF 25/660 reads (4%) | called by muse, mutect2
- TRERF1 | c.1683G>A p.P561= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs376132204, COSV100551717; called by muse, mutect2
- TTC1 | c.429C>T p.L143= | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as rs147828350; called by muse, mutect2, varscan2
- UCHL1 | c.435C>T p.A145= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs142811772; called by muse, mutect2, varscan2
- ZNF335 | c.1929C>T p.H643= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1202750165, COSV59816160; called by muse, mutect2, varscan2
- GCNT2 | c.926-35276C>T | Intron (SNP) | VAF 38/255 reads (15%) | catalogued as rs775325397, COSV53942623; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.930-6242C>T | Intron (SNP) | VAF 18/35 reads (51%) | catalogued as rs748559516, COSV100423892; called by muse, mutect2, varscan2
- WASF4P | n.61G>A | RNA (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
